Gene-level copy-number profile of tumor specimen TCGA-24-2254-01A from TCGA case TCGA-24-2254, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.8 years (24,407 days).
Specimen TCGA-24-2254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ad900317-46f7-4681-8fb1-692f07f48e38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2254-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 843 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3b95385-2c07-4a6b-9a83-75a857041465

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 22,274; copy number 2: 31,426; copy number 3: 5,765; copy number 4: 233; copy number 5: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2254-01A-01D-0663-01): tumor purity 0.81, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:74,120,255–74,709,963, 7 genes (within-gene range 0–1): AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,684,572–147,370,656, 21 genes, copy number 5 (within-gene range 3–5): GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P, RPL21P71.
- chr3:152,449,272–154,121,347, 21 genes, copy number 5: Y_RNA, AC026347.1, AC092924.1, AC092924.2, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1.
- chr9:120,600,811–122,331,337, 33 genes, copy number 5: MEGF9, AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19, TRAF1, C5, CNTRL, RAB14, RN7SL181P, GSN, AL513122.1, AL513122.2, GSN-AS1, STOM, AL359644.1, GGTA1, RN7SL187P, HMGB1P37, DAB2IP, AL357936.1, AL596244.1, TTLL11, TTLL11-IT1, MIR4478, NDUFA8, MORN5, LHX6, RBM18, MRRF.

Autosomal genes at a single copy (total copy number 1): 22,274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
